Somatic mutation profile of tumor specimen TCGA-EJ-7125-01A (aliquot TCGA-EJ-7125-01A-11D-1961-08) from TCGA case TCGA-EJ-7125, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 45.0 years (16,425 days).
Specimen TCGA-EJ-7125-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6cb47b6c-1fdc-4705-b761-46fc2a089044.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-7125-10A (Blood Derived Normal), aliquot TCGA-EJ-7125-10A-01D-1961-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/edcfed1f-b6c9-4656-8da3-c9fd2df65a0a

The open-access MAF lists 24 somatic variants for this specimen: 19 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 3, Frame Shift Ins 2, 5'UTR 1, 5'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>G p.R132G | Missense Mutation (SNP) | VAF 21/80 reads (26%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.883); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ALPI | c.745G>A p.G249R | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.251); catalogued as rs766666691, COSV55013296, COSV99785747; called by muse, mutect2, varscan2
- ANAPC1 | c.1174A>G p.N392D | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.027); catalogued as rs540910667, COSV61974825; called by muse, mutect2, varscan2
- ARHGEF18 | c.3277G>A p.G1093R (on ENST00000359920 / NM_001130955.2; = p.G989R on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/100 reads (46%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.034); catalogued as rs776440309, COSV60468060; called by muse, mutect2, varscan2
- CASP7 | c.745C>A p.L249M | Missense Mutation (SNP) | VAF 55/188 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV61881342; called by mutect2, varscan2
- CEACAM20 | c.68T>C p.V23A | Missense Mutation (SNP) | VAF 39/135 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV57601060; called by muse, mutect2, varscan2
- COL15A1 | c.1766G>T p.G589V | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.207); catalogued as COSV66642309; called by muse, mutect2, varscan2
- ELAVL4 | c.317C>T p.T106I | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.072); catalogued as rs758825213, COSV100836641, COSV63915128, COSV63918303; called by muse, mutect2, varscan2
- LRRC75B | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 89/230 reads (39%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs376304947; called by muse, mutect2, varscan2
- MCMBP | c.1639G>A p.V547M | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.244); catalogued as rs769222269, COSV63508743; called by muse, mutect2, varscan2
- MECOM | c.2468C>T p.S823L (on ENST00000468789 / NM_001105078.4; = p.S1011L on NM_004991.4) | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs540158912, COSV52961560; called by muse, mutect2, varscan2
- MINDY4 | c.500C>T p.T167M | Missense Mutation (SNP) | VAF 62/164 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs757043983, COSV54672348; called by muse, mutect2, varscan2
- NSA2 | c.406A>C p.I136L | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV57187710; called by muse, mutect2, varscan2
- ROBO2 | c.1736T>A p.L579H | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.329); catalogued as COSV59902267; called by muse, mutect2, varscan2
- SDK2 | c.6257C>T p.S2086L | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs201330590, COSV66183028; called by muse, mutect2, varscan2
- TMEM211 | c.589G>T p.E197* (on ENST00000423535; = p.E126* on NM_001001663.3) | Nonsense Mutation (SNP) | VAF 45/136 reads (33%) | catalogued as COSV66954083; called by muse, mutect2, varscan2
- ZBTB48 | c.1515A>T p.Q505H | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV66553087; called by muse, mutect2, varscan2
- KDM6A | c.1155_1158dup p.T387* | Frame Shift Ins (INS) | VAF 3/25 reads (12%) | called by mutect2, pindel
- MIB1 | c.1568dup p.L523Ffs*18 | Frame Shift Ins (INS) | VAF 17/67 reads (25%) | called by mutect2, pindel, varscan2
- ARNT2 | c.1371A>T p.S457= | Silent (SNP) | VAF 33/99 reads (33%) | catalogued as COSV57582782; called by muse, mutect2, varscan2
- MUC5B | c.2424G>A p.A808= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as rs747140553, COSV101500745, COSV71590591; called by muse, mutect2, varscan2
- TOPBP1 | c.2898A>G p.V966= | Silent (SNP) | VAF 23/67 reads (34%) | catalogued as COSV53433742; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65506058 del TTG | 5'Flank (DEL) | VAF 17/73 reads (23%) | catalogued as rs1288137668; called by mutect2, pindel, varscan2
- FBXO42 | c.-1C>T | 5'UTR (SNP) | VAF 14/54 reads (26%) | catalogued as COSV100981929; called by muse, mutect2, varscan2
